Somatic mutation profile of tumor specimen 0DVPOR from CCDI case PBCMRF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DVPOR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c508af8-1a53-40f3-a01e-8a4797a1d4de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb78fcf8-6a6f-4f32-b96d-74941b0de38a

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 3, Nonsense Mutation 2, Frame Shift Del 2, 5'UTR 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 216/518 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 268/600 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, varscan2
- AHDC1 | c.3112_3114del p.F1038del | In Frame Del (DEL) | VAF 128/322 reads (40%) | catalogued as rs762446869; called by pindel, varscan2
- ARHGEF18 | c.2545C>T p.R849C (on ENST00000359920 / NM_001130955.2; = p.R745C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 160/180 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1434713248; called by muse, varscan2
- ATR | c.6442C>T p.R2148* | Nonsense Mutation (SNP) | VAF 562/1038 reads (54%) | catalogued as rs1455160611, COSV100637579; called by muse, varscan2
- CHRM3 | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 176/434 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs145638222; called by muse, varscan2
- CHURC1 | c.38C>G p.S13C | Missense Mutation (SNP) | VAF 165/403 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV63036284; called by muse, varscan2
- CREBBP | c.3779C>T p.T1260M | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs777015995, COSV52118625; called by muse, varscan2
- MST1R | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 289/660 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs878910700, COSV56576108; called by muse, varscan2
- MVP | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 202/522 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs754161146, COSV100651455; called by muse, varscan2
- OR10A6 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 349/832 reads (42%) | catalogued as rs771599604; called by muse, varscan2
- PDGFRA | c.1607T>A p.V536E | Missense Mutation (SNP) | VAF 354/1242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57271679; called by muse, varscan2
- VRTN | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs760738333, COSV56440875, COSV56442452; called by muse, varscan2
- WNK2 | c.3341C>T p.T1114M | Missense Mutation (SNP) | VAF 216/512 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as rs372487751; called by muse, varscan2
- ATRX | c.6639_6642del p.L2214* | Frame Shift Del (DEL) | VAF 375/890 reads (42%) | called by pindel, varscan2
- BRCA2 | c.8953+4_8953+7del p.X2985_splice | Splice Site (DEL) | VAF 287/732 reads (39%) | called by pindel, varscan2
- FBXW7 | c.802dup p.M268Nfs*19 (on ENST00000281708 / NM_001349798.2; = p.M188Nfs*19 on NM_018315.5) | Frame Shift Ins (INS) | VAF 920/1656 reads (56%) | called by pindel, varscan2
- FOXD3 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 196/468 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PLPPR2 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 243/268 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- SRCAP | c.6043T>C p.W2015R | Missense Mutation (SNP) | VAF 402/896 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.648); called by muse, varscan2
- TP53 | c.631_632del p.T211Ffs*4 | Frame Shift Del (DEL) | VAF 220/697 reads (32%) | called by pindel, varscan2
- ZNF34 | c.1529A>G p.K510R | Missense Mutation (SNP) | VAF 152/336 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); called by muse, varscan2
- ZNF512B | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 170/364 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.228); called by muse, varscan2
- COL16A1 | c.897G>A p.Q299= | Silent (SNP) | VAF 176/471 reads (37%) | called by muse, varscan2
- FBRS | c.1317G>A p.P439= (on ENST00000287468; = p.P959= on NM_001105079.3) | Silent (SNP) | VAF 218/506 reads (43%) | catalogued as rs1028079327; called by muse, varscan2
- GRID2 | c.1551C>T p.A517= | Silent (SNP) | VAF 538/588 reads (91%) | catalogued as rs560303075, COSV56190911, COSV56287917; called by muse, varscan2
- ATAD3B | c.325-28C>T | Intron (SNP) | VAF 236/504 reads (47%) | called by muse, varscan2
- BAIAP3 | c.2747+21A>C | Intron (SNP) | VAF 85/184 reads (46%) | called by muse, varscan2
- DUSP9 | c.-26T>A | 5'UTR (SNP) | VAF 150/451 reads (33%) | called by muse, varscan2
- PCF11 | c.2092+324C>T | Intron (SNP) | VAF 487/1092 reads (45%) | catalogued as rs763698094; called by muse, varscan2
- RBM47 | c.-155+469T>G | Intron (SNP) | VAF 118/324 reads (36%) | called by muse, varscan2
- SOWAHD | c.-40C>T | 5'UTR (SNP) | VAF 146/380 reads (38%) | called by muse, varscan2
